Somatic mutation profile of tumor specimen TCGA-77-6842-01A (aliquot TCGA-77-6842-01A-11D-1945-08) from TCGA case TCGA-77-6842, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 79.0 years (28,861 days).
Specimen TCGA-77-6842-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0be30889-2b92-447f-90e4-f0420f222cdb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-77-6842-10A (Blood Derived Normal), aliquot TCGA-77-6842-10A-01D-1945-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/37b25f90-23bc-4284-83bc-a19066b22edd

The open-access MAF lists 389 somatic variants for this specimen: 302 protein-altering or splice-affecting, 79 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 259, Silent 79, Nonsense Mutation 21, Splice Site 12, Frame Shift Del 7, Intron 4, RNA 3, 5'UTR 1, Splice Region 1, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PRSS1 | c.68A>G p.K23R | Missense Mutation (SNP) | VAF 43/191 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.32); catalogued as rs111033567, CM991072, COSV100297661; ClinVar: likely pathogenic; called by muse, varscan2
- PTEN | c.71A>G p.D24G | Missense Mutation (SNP) | VAF 10/72 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.193); catalogued as rs797044910, CM110138, CM141438, COSV64293188, COSV64296384, COSV64307484; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AASS | c.803A>T p.H268L | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.94); catalogued as COSV100741624; called by muse, mutect2, varscan2
- ACE | c.2858G>T p.R953L | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99326256; called by muse, mutect2, varscan2
- ACLY | c.2111A>C p.Y704S | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs782683248, COSV100709488; called by muse, mutect2, varscan2
- ACMSD | c.257C>A p.P86H | Missense Mutation (SNP) | VAF 91/224 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99298732; called by muse, mutect2, varscan2
- ACVRL1 | c.1205G>T p.G402V | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM085224, COSV101187773; called by muse, mutect2, varscan2
- ADAM2 | c.54T>C p.S18= | Splice Region (SNP) | VAF 31/79 reads (39%) | catalogued as rs1371752525, COSV99696578; called by muse, mutect2, varscan2
- ADAMTS15 | c.1360G>T p.V454L | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV100143032, COSV54509533; called by muse, mutect2, varscan2
- AHSP | c.25G>T p.D9Y | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56529255; called by muse, mutect2, varscan2
- AIFM3 | c.511-1G>C p.X171_splice | Splice Site (SNP) | VAF 6/36 reads (17%) | catalogued as COSV100104138; called by muse, varscan2
- ALDH18A1 | c.1033G>C p.E345Q | Missense Mutation (SNP) | VAF 37/182 reads (20%) | SIFT tolerated (0.86); PolyPhen benign (0.017); catalogued as COSV100973033; called by muse, mutect2, varscan2
- AMOTL1 | c.1562G>A p.R521Q | Missense Mutation (SNP) | VAF 9/134 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.312); catalogued as COSV58566021; called by muse, mutect2
- ANGPT4 | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.138); catalogued as COSV101124613; called by muse, mutect2, varscan2
- ANKRD30A | c.3781A>G p.K1261E (on ENST00000611781; = p.K1205E on NM_052997.2) | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.087); catalogued as COSV100652747; called by muse, mutect2, varscan2
- ANLN | c.2418G>T p.L806F | Missense Mutation (SNP) | VAF 74/169 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV99731714; called by muse, mutect2, varscan2
- ANO6 | c.2223G>T p.M741I | Missense Mutation (SNP) | VAF 33/122 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV100262092; called by muse, mutect2, varscan2
- APAF1 | c.2128A>G p.S710G (on ENST00000551964 / NM_181861.2; = p.S699G on NM_001160.3) | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV100452234; called by muse, mutect2, varscan2
- APOBEC1 | c.565C>A p.L189I | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.987); catalogued as COSV99980944; called by muse, mutect2, varscan2
- ARHGAP15 | c.1003G>T p.E335* | Nonsense Mutation (SNP) | VAF 73/219 reads (33%) | catalogued as COSV54503341; called by muse, mutect2, varscan2
- ARHGEF38 | c.462G>T p.L154F | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.915); catalogued as COSV99486013; called by muse, mutect2, varscan2
- ART3 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.532); catalogued as COSV100587482; called by muse, mutect2, varscan2
- ASIC2 | c.889G>T p.D297Y | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV56765303, COSV99859063; called by muse, mutect2, varscan2
- ASIC2 | c.380A>C p.H127P | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV100725441; called by muse, mutect2, varscan2
- ATRX | c.7073G>A p.W2358* | Nonsense Mutation (SNP) | VAF 5/44 reads (11%) | catalogued as COSV100969883; called by muse, mutect2, varscan2
- B3GALT2 | c.419T>C p.I140T | Missense Mutation (SNP) | VAF 54/159 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as rs763003827, COSV100813552; called by muse, mutect2, varscan2
- BCO1 | c.778A>C p.M260L | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV99257347; called by muse, mutect2, varscan2
- BIRC6 | c.3134G>T p.C1045F | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101427749; called by muse, mutect2, varscan2
- CA7 | c.434T>A p.V145E | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100623711; called by muse, mutect2, varscan2
- CCDC110 | c.1322T>C p.I441T | Missense Mutation (SNP) | VAF 48/156 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.083); catalogued as COSV100293586; called by muse, mutect2, varscan2
- CCDC150 | c.108G>T p.M36I | Missense Mutation (SNP) | VAF 51/142 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV99776397; called by muse, mutect2, varscan2
- CCDC191 | c.2216T>C p.I739T | Missense Mutation (SNP) | VAF 60/181 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as rs1391968486, COSV99877843; called by muse, mutect2, varscan2
- CCDC73 | c.2000T>C p.L667P | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.829); catalogued as COSV100066244; called by muse, mutect2, varscan2
- CDK14 | c.1232A>T p.Q411L (on ENST00000380050 / NM_001287135.2; = p.Q393L on NM_012395.3) | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.237); catalogued as COSV99723448; called by muse, mutect2, varscan2
- CECR2 | c.3254G>T p.G1085V (on ENST00000342247 / NM_001290047.2; = p.G901V on NM_001290046.1) | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.784); catalogued as COSV99376813; called by muse, mutect2, varscan2
- CEP170B | c.3892C>G p.R1298G (on ENST00000453495; = p.R1227G on NM_015005.3) | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV52044986, COSV52045390, COSV99229650; called by muse, mutect2
- CEP250 | c.7109A>G p.K2370R | Missense Mutation (SNP) | VAF 61/117 reads (52%) | SIFT tolerated (0.39); PolyPhen benign (0.011); catalogued as COSV61172886; called by muse, mutect2, varscan2
- CH25H | c.377A>T p.H126L | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV100897327; called by muse, mutect2, varscan2
- CHD6 | c.8059G>T p.E2687* | Nonsense Mutation (SNP) | VAF 23/207 reads (11%) | catalogued as COSV100950487; called by muse, mutect2, varscan2
- CLCA2 | c.2665C>A p.P889T | Missense Mutation (SNP) | VAF 76/213 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.115); catalogued as COSV100991300; called by muse, mutect2, varscan2
- CLPTM1L | c.1104G>C p.L368F | Missense Mutation (SNP) | VAF 14/232 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.083); catalogued as COSV100306715, COSV100306743; called by muse, mutect2
- CNTNAP4 | c.1757A>G p.H586R | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1359997219, COSV100269057; called by muse, mutect2, varscan2
- COL12A1 | c.6341-1G>T p.X2114_splice | Splice Site (SNP) | VAF 8/33 reads (24%) | catalogued as COSV100485237; called by muse, mutect2, varscan2
- COL12A1 | c.6341-2A>T p.X2114_splice | Splice Site (SNP) | VAF 9/35 reads (26%) | catalogued as COSV100485238; called by muse, mutect2, varscan2
- COX18 | c.593C>G p.S198* | Nonsense Mutation (SNP) | VAF 14/73 reads (19%) | catalogued as COSV99886909; called by muse, mutect2, varscan2
- CROCC | c.5211G>C p.Q1737H | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100978028; called by muse, mutect2, varscan2
- CRYBA2 | c.445G>T p.A149S | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.169); catalogued as COSV99838031; called by muse, mutect2, varscan2
- CUL5 | c.2197C>A p.Q733K | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.236); catalogued as COSV101263621; called by muse, mutect2, varscan2
- CYB5R4 | c.413A>G p.D138G | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV100859432; called by muse, mutect2, varscan2
- CYP26B1 | c.523C>G p.H175D | Missense Mutation (SNP) | VAF 44/137 reads (32%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV99134190; called by muse, mutect2, varscan2
- DAPK2 | c.43A>T p.K15* | Nonsense Mutation (SNP) | VAF 41/81 reads (51%) | catalogued as COSV99976988; called by muse, mutect2, varscan2
- DCAF8L1 | c.400G>T p.D134Y | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.398); catalogued as COSV101491370; called by muse, mutect2, varscan2
- DDX19A | c.1094A>G p.E365G | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV100156116; called by muse, mutect2, varscan2
- DEFB135 | c.219A>G p.I73M | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0.325); catalogued as rs1173930495, COSV101198531; called by muse, mutect2, varscan2
- DMBT1 | c.3550A>G p.I1184V (on ENST00000338354 / NM_001377530.1; = p.I685V on NM_004406.3) | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.033); catalogued as COSV100351874; called by muse, mutect2, varscan2
- DMBT1 | c.6601C>T p.R2201C (on ENST00000338354 / NM_001377530.1; = p.R1444C on NM_004406.3) | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs374738106, COSV100352073; called by muse, mutect2, varscan2
- DNAH5 | c.5173C>A p.L1725I | Missense Mutation (SNP) | VAF 28/254 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV99444021; called by muse, mutect2, varscan2
- DNAH7 | c.808C>G p.H270D | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100413584, COSV99044790; called by muse, mutect2, varscan2
- DNM3 | c.894C>A p.N298K | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV100797730; called by muse, mutect2, varscan2
- DOCK9 | c.397G>A p.E133K (on ENST00000376460 / NM_001366676.2; = p.E134K on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.185); catalogued as COSV100237607; called by muse, varscan2
- DSG3 | c.1985C>A p.S662* | Nonsense Mutation (SNP) | VAF 60/132 reads (45%) | catalogued as COSV99933661; called by muse, mutect2, varscan2
- DYRK1A | c.1339G>T p.A447S | Missense Mutation (SNP) | VAF 45/84 reads (54%) | SIFT tolerated (0.54); PolyPhen benign (0.019); catalogued as COSV100117353; called by muse, mutect2, varscan2
- EBI3 | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV99696001; called by muse, mutect2, varscan2
- EFNA5 | c.557A>T p.E186V | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.145); catalogued as COSV100320713; called by muse, mutect2, varscan2
- EFNA5 | c.556G>C p.E186Q | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.091); catalogued as COSV100320716; called by muse, mutect2, varscan2
- ENPP6 | c.485C>A p.T162K | Missense Mutation (SNP) | VAF 96/265 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as COSV57067600, COSV99698394; called by muse, mutect2, varscan2
- EPB41 | c.1112A>G p.H371R (on ENST00000343067 / NM_001166005.2; = p.H162R on NM_004437.4) | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as rs778928272, COSV58054922; called by muse, mutect2, varscan2
- EPHB1 | c.1807C>T p.P603S | Missense Mutation (SNP) | VAF 29/180 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101212562; called by muse, mutect2, varscan2
- ERICH3 | c.3728T>A p.L1243Q | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.134); catalogued as COSV100443188; called by muse, mutect2, varscan2
- EXOC1 | c.1763G>T p.R588L | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.176); catalogued as COSV100637732; called by muse, mutect2, varscan2
- FAM83B | c.515G>C p.R172P | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100173938, COSV100174318, COSV60920027; called by muse, mutect2, varscan2
- FBXO30 | c.619A>C p.I207L | Missense Mutation (SNP) | VAF 34/228 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.119); catalogued as COSV99394938; called by muse, mutect2, varscan2
- FGD5 | c.3055C>A p.R1019S | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.764); catalogued as COSV53239489, COSV99547128; called by muse, mutect2, varscan2
- FMR1 | c.1339A>T p.S447C | Missense Mutation (SNP) | VAF 78/122 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV99502883; called by muse, mutect2, varscan2
- GHRL | c.108+1G>C p.X36_splice | Splice Site (SNP) | VAF 8/30 reads (27%) | catalogued as COSV99813866; called by muse, mutect2, varscan2
- GLI3 | c.4215G>T p.Q1405H | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.635); catalogued as COSV101229686; called by muse, mutect2, varscan2
- GLP2R | c.1352G>T p.W451L | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1254742134, COSV99301466; called by muse, mutect2, varscan2
- GPC6 | c.136G>T p.D46Y | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.595); catalogued as COSV100987951; called by muse, varscan2
- GRIN2A | c.2506A>G p.I836V | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV100407864; called by muse, mutect2, varscan2
- GRIN2B | c.2672T>C p.M891T | Missense Mutation (SNP) | VAF 58/163 reads (36%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.747); catalogued as COSV101662870; called by muse, mutect2, varscan2
- GRM1 | c.613G>T p.V205F | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV99263552; called by muse, mutect2, varscan2
- GRM1 | c.1895A>G p.Y632C | Missense Mutation (SNP) | VAF 46/191 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1416484958, COSV99263557; called by muse, mutect2, varscan2
- GRM5 | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs1409555487, COSV100555021, COSV59605587; called by muse, varscan2
- GUCY1A2 | c.395A>T p.N132I | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.952); catalogued as COSV99972296; called by muse, mutect2, varscan2
- H4C2 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as rs1296621230, COSV55138254, COSV99774715, COSV99774982; called by muse, mutect2, varscan2
- HAVCR1 | c.1056C>A p.D352E | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.391); catalogued as COSV100207850; called by muse, mutect2, varscan2
- HNRNPH2 | c.1191G>A p.M397I | Missense Mutation (SNP) | VAF 117/207 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100346840, COSV57266002; called by muse, mutect2, varscan2
- HTT | c.8213T>C p.L2738P | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100750305; called by muse, mutect2, varscan2
- IFNAR1 | c.344A>G p.Y115C | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as rs745609676, COSV99531420; called by muse, mutect2, varscan2
- IFNGR1 | c.7C>G p.L3V | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.049); catalogued as COSV100880391; called by muse, mutect2
- IFT80 | c.1665-2A>T p.X555_splice | Splice Site (SNP) | VAF 21/70 reads (30%) | catalogued as COSV100424278; called by muse, mutect2, varscan2
- IGHV1-2 | c.118T>G p.S40A | Missense Mutation (SNP) | VAF 69/137 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs11553014; called by muse, mutect2, varscan2
- IMMP1L | c.112G>T p.G38* | Nonsense Mutation (SNP) | VAF 6/35 reads (17%) | catalogued as COSV99540581; called by muse, varscan2
- ING3 | c.48G>T p.M16I | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.708); catalogued as COSV100187265; called by muse, mutect2, varscan2
- ITPR2 | c.6536G>T p.R2179L | Missense Mutation (SNP) | VAF 54/132 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV101189777; called by muse, mutect2, varscan2
- JAG1 | c.1775G>A p.R592Q | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.259); catalogued as rs1436726865, CX122869; called by muse, mutect2
- KCNH7 | c.2626C>G p.R876G | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV100146782, COSV59796250; called by muse, mutect2
- KCNN3 | c.994G>A p.G332S | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV99677169; called by muse, mutect2, varscan2
- KIAA1109 | c.10702C>G p.Q3568E | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.9); catalogued as COSV99145458; called by muse, mutect2, varscan2
- KIAA1109 | c.14190G>C p.L4730F | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV99145461; called by muse, mutect2, varscan2
- KIAA1210 | c.2138A>G p.Q713R | Missense Mutation (SNP) | VAF 26/42 reads (62%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV101273886; called by muse, mutect2, varscan2
- KMT2C | c.12431T>C p.L4144P | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.04); catalogued as COSV100065163; called by muse, mutect2, varscan2
- LHCGR | c.1360G>T p.V454F | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99683008; called by muse, mutect2, varscan2
- LIG4 | c.1210C>T p.Q404* | Nonsense Mutation (SNP) | VAF 7/113 reads (6%) | catalogued as rs1566364794, COSV100799669; called by muse, mutect2
- LILRA2 | c.207G>T p.W69C | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99252585; called by muse, mutect2, varscan2
- LILRA4 | c.377C>A p.S126Y | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99392808; called by muse, mutect2, varscan2
- LPA | c.50-1G>T p.X17_splice | Splice Site (SNP) | VAF 86/233 reads (37%) | catalogued as COSV100305903; called by muse, mutect2, varscan2
- LRP1B | c.7505G>A p.R2502K | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.761); catalogued as rs917496372, COSV101250860, COSV101260642; called by muse, mutect2
- LRP1B | c.3312G>T p.W1104C | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as COSV101250862; called by muse, mutect2, varscan2
- LRP1B | c.3311G>T p.W1104L | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV101250863, COSV67190351; called by muse, mutect2, varscan2
- LRP2 | c.521C>T p.S174L | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV55567895; called by muse, mutect2, varscan2
- MACO1 | c.1365G>T p.Q455H | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.915); catalogued as COSV100974971; called by muse, mutect2, varscan2
- MARCO | c.230T>A p.L77Q | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.831); catalogued as COSV100503116; called by muse, mutect2, varscan2
- MFN1 | c.2210G>A p.S737N | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.306); catalogued as COSV54938601; called by muse, mutect2, varscan2
- MLANA | c.315G>C p.E105D | Missense Mutation (SNP) | VAF 7/192 reads (4%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.805); catalogued as COSV101199941; called by muse, mutect2
- MOG | c.193G>T p.E65* | Nonsense Mutation (SNP) | VAF 39/142 reads (27%) | catalogued as COSV100972952, COSV65322133; called by muse, mutect2, varscan2
- MORC3 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101264819, COSV68687991; called by muse, mutect2
- MR1 | c.901G>T p.V301L | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV99294746; called by muse, mutect2, varscan2
- MROH2B | c.3325G>A p.E1109K | Missense Mutation (SNP) | VAF 45/264 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.137); catalogued as rs1427712030, COSV101270924, COSV68181885, COSV68186148; called by muse, mutect2, varscan2
- MS4A8 | c.289del p.E97Nfs*45 | Frame Shift Del (DEL) | VAF 54/163 reads (33%) | catalogued as COSV55754311; called by mutect2, pindel, varscan2
- MTA1 | c.1475C>T p.P492L | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.84); PolyPhen benign (0.007); catalogued as COSV58757713; called by muse, mutect2, varscan2
- MUC16 | c.28358C>T p.S9453F | Missense Mutation (SNP) | VAF 45/133 reads (34%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.534); catalogued as COSV101197669, COSV67480819; called by muse, mutect2, varscan2
- MYCBP2 | c.1091C>G p.S364C (on ENST00000357337; = p.S402C on NM_015057.5) | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV100628991; called by muse, mutect2, varscan2
- MYH2 | c.4381G>C p.E1461Q | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.882); catalogued as rs1383258246, COSV99819122; called by muse, mutect2, varscan2
- MYLK3 | c.854G>T p.G285V | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.255); catalogued as COSV101189037; called by muse, mutect2, varscan2
- MYO10 | c.2516G>C p.R839T | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV99944485; called by muse, mutect2
- MYO16 | c.100C>G p.R34G | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51779591, COSV99193431; called by muse, mutect2, varscan2
- MYO1A | c.95A>T p.Y32F | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100270484; called by muse, mutect2, varscan2
- MYO1B | c.1415A>G p.D472G | Missense Mutation (SNP) | VAF 112/254 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100268481; called by muse, mutect2, varscan2
- MYO5B | c.4231G>T p.E1411* | Nonsense Mutation (SNP) | VAF 70/161 reads (43%) | catalogued as COSV99543352; called by muse, mutect2, varscan2
- MYO5C | c.3113A>G p.D1038G | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV99953936; called by muse, mutect2, varscan2
- MYT1L | c.2592A>T p.K864N | Missense Mutation (SNP) | VAF 60/144 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV101218297; called by muse, mutect2, varscan2
- NAA11 | c.660C>G p.D220E | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as COSV99727131; called by muse, varscan2
- NAP1L1 | c.181G>T p.E61* | Nonsense Mutation (SNP) | VAF 45/135 reads (33%) | catalogued as COSV99673624; called by muse, mutect2, varscan2
- NCAPD3 | c.2317A>C p.T773P | Missense Mutation (SNP) | VAF 18/470 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.229); catalogued as COSV101599331, COSV73258561; called by muse, mutect2
- NDUFS1 | c.1871G>C p.R624T | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1414156876, COSV99260229; called by muse, mutect2, varscan2
- NIBAN1 | c.2528G>T p.G843V | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.006); catalogued as rs778170447, COSV100836159; called by muse, mutect2, varscan2
- NIPA1 | c.582C>G p.I194M | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100507687; called by muse, mutect2
- NLRP11 | c.181G>C p.E61Q | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as COSV100789598, COSV100789614; called by muse, mutect2, varscan2
- NLRP3 | c.2126C>G p.S709C | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.125); catalogued as COSV100275123; called by muse, mutect2, varscan2
- NMD3 | c.1179G>C p.M393I | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV100664575; called by muse, mutect2, varscan2
- NOS1 | c.3921G>T p.K1307N | Missense Mutation (SNP) | VAF 65/182 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as COSV100499913; called by muse, mutect2, varscan2
- NPY1R | c.137C>G p.A46G | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.783); catalogued as COSV99648413; called by muse, mutect2, varscan2
- NPY2R | c.660T>A p.S220R | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100279402, COSV61527914; called by muse, mutect2, varscan2
- OPRD1 | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 47/114 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0.028); catalogued as rs752362079, COSV99330035; called by muse, mutect2, varscan2
- OR10H1 | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.718); catalogued as COSV100612337; called by muse, mutect2, varscan2
- OR13F1 | c.20C>A p.T7K | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV100594663; called by muse, mutect2, varscan2
- OR2G6 | c.16A>G p.N6D | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV58574939; called by muse, mutect2, varscan2
- OR2J3 | c.530T>C p.V177A | Missense Mutation (SNP) | VAF 55/137 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as rs763950021, COSV101013542; called by muse, mutect2, varscan2
- OR2M5 | c.481G>T p.V161L | Missense Mutation (SNP) | VAF 102/286 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.213); catalogued as COSV100822718; called by muse, mutect2, varscan2
- OR2T10 | c.65C>G p.S22* | Nonsense Mutation (SNP) | VAF 19/54 reads (35%) | catalogued as COSV100393561, COSV57896483; called by muse, mutect2, varscan2
- OR4A5 | c.721A>T p.S241C | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.106); catalogued as COSV60521479; called by muse, mutect2, varscan2
- OR51M1 | c.548C>A p.S183Y | Missense Mutation (SNP) | VAF 85/202 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.123); catalogued as COSV100150094, COSV60785117; called by muse, mutect2, varscan2
- OR56B1 | c.634G>C p.A212P | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100402514, COSV100402720; called by muse, mutect2
- OR5T1 | c.362C>G p.T121S | Missense Mutation (SNP) | VAF 66/199 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.226); catalogued as COSV100478664; called by muse, mutect2, varscan2
- OR6Q1 | c.312G>C p.Q104H | Missense Mutation (SNP) | VAF 48/164 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100109226; called by muse, mutect2
- OR8D1 | c.198G>C p.L66F | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100766511; called by muse, mutect2, varscan2
- OR8I2 | c.481T>A p.W161R | Missense Mutation (SNP) | VAF 31/156 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.12); catalogued as COSV100135800, COSV100136293; called by muse, mutect2, varscan2
- OR8K3 | c.163T>A p.L55M | Missense Mutation (SNP) | VAF 41/206 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs201367606, COSV100449634, COSV57131138; called by muse, mutect2, varscan2
- OTUD4 | c.1379A>G p.Y460C (on ENST00000447906 / NM_001366057.1; = p.Y395C on NM_001102653.1) | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs766465592, COSV101485859; called by muse, mutect2, varscan2
- P2RY8 | c.775G>C p.A259P | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.691); catalogued as COSV101183926; called by muse, mutect2, varscan2
- PALLD | c.412C>T p.R138* | Nonsense Mutation (SNP) | VAF 21/85 reads (25%) | catalogued as rs201653170, COSV99823679; called by muse, mutect2, varscan2
- PAPPA2 | c.4264A>G p.T1422A | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.101); catalogued as COSV100867462; called by muse, mutect2, varscan2
- PAX4 | c.563-2A>G p.X188_splice | Splice Site (SNP) | VAF 10/38 reads (26%) | catalogued as COSV100489910; called by muse, mutect2, varscan2
- PCDH10 | c.1639G>T p.D547Y | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99992768; called by muse, mutect2, varscan2
- PDIA6 | c.294T>A p.F98L | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99694335; called by muse, mutect2, varscan2
- PFAS | c.2746G>T p.V916F | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.45); catalogued as COSV100118717; called by muse, mutect2, varscan2
- PHACTR2 | c.1136C>T p.P379L | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs773202916, COSV59854890; called by muse, mutect2, varscan2
- PI15 | c.641+2T>C p.X214_splice | Splice Site (SNP) | VAF 15/69 reads (22%) | catalogued as COSV99477745; called by muse, mutect2, varscan2
- PIK3C2A | c.1531A>T p.S511C | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.423); catalogued as COSV99790111; called by muse, mutect2, varscan2
- PKHD1L1 | c.2250C>A p.Y750* | Nonsense Mutation (SNP) | VAF 9/24 reads (38%) | catalogued as rs977556994, COSV101005164; called by muse, mutect2, varscan2
- PLCH1 | c.2403G>T p.M801I (on ENST00000340059 / NM_001130960.2; = p.M813I on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs765443196, COSV100395379; called by muse, mutect2, varscan2
- PLEKHA4 | c.1051G>T p.G351C | Missense Mutation (SNP) | VAF 11/146 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99611968; called by muse, mutect2
- POLE | c.3479G>A p.R1160H | Missense Mutation (SNP) | VAF 38/156 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs757902862, COSV57688771; called by muse, mutect2, varscan2
- PRAME | c.388C>A p.Q130K | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.669); catalogued as COSV101286995; called by muse, mutect2, varscan2
- PRDM5 | c.243G>T p.W81C | Missense Mutation (SNP) | VAF 56/295 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV99309644; called by muse, mutect2, varscan2
- PRDM5 | c.242G>T p.W81L | Missense Mutation (SNP) | VAF 56/295 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.214); catalogued as COSV99309646, COSV99310560; called by muse, mutect2, varscan2
- PRDM9 | c.467G>T p.G156V | Missense Mutation (SNP) | VAF 26/234 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.708); catalogued as COSV57001777, COSV99689661; called by muse, mutect2, varscan2
- PRDM9 | c.1688G>C p.W563S | Missense Mutation (SNP) | VAF 237/339 reads (70%) | SIFT tolerated (0.66); PolyPhen benign (0.102); catalogued as COSV99689663; called by muse, mutect2, varscan2
- PROZ | c.574-1G>C p.X192_splice | Splice Site (SNP) | VAF 33/77 reads (43%) | catalogued as COSV100720245; called by muse, mutect2, varscan2
- PRPF40A | c.2300C>T p.A767V | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.263); catalogued as COSV101344155; called by muse, mutect2, varscan2
- PSMC4 | c.947C>G p.T316S | Missense Mutation (SNP) | VAF 36/190 reads (19%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.999); catalogued as COSV99338085; called by muse, mutect2, varscan2
- PSMD1 | c.999G>A p.M333I | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100433295; called by muse, mutect2, varscan2
- PTCH2 | c.1754G>A p.G585E | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.038); catalogued as COSV100941872, COSV100942176; called by muse, mutect2, varscan2
- PTDSS1 | c.632C>T p.A211V | Missense Mutation (SNP) | VAF 72/213 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.348); catalogued as COSV61265077; called by muse, mutect2, varscan2
- PTHLH | c.107G>C p.R36T | Missense Mutation (SNP) | VAF 46/147 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV52369202; called by muse, mutect2, varscan2
- PTPRZ1 | c.4549G>T p.D1517Y | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV101099322; called by mutect2, varscan2
- PYHIN1 | c.1474C>A p.P492T | Missense Mutation (SNP) | VAF 9/67 reads (13%) | PolyPhen benign (0.031); catalogued as COSV100932533, COSV63731110; called by muse, mutect2, varscan2
- PYHIN1 | c.1475C>A p.P492H | Missense Mutation (SNP) | VAF 9/66 reads (14%) | PolyPhen benign (0.37); catalogued as COSV63730754; called by muse, mutect2, varscan2
- RAB36 | c.520C>T p.L174F | Missense Mutation (SNP) | VAF 27/205 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.861); catalogued as rs530163185, COSV99572063; called by muse, mutect2, varscan2
- RAB4A | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 58/145 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.21); catalogued as rs747437276, COSV100796973; called by muse, mutect2, varscan2
- RALB | c.376G>T p.V126L | Missense Mutation (SNP) | VAF 41/213 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs762186246, COSV55604690, COSV99732374; called by muse, mutect2, varscan2
- RBPJL | c.961C>A p.P321T | Missense Mutation (SNP) | VAF 77/151 reads (51%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100643416; called by muse, mutect2, varscan2
- RD3 | c.424T>C p.W142R | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV100879186; called by muse, mutect2, varscan2
- REG1A | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 117/389 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV99286626; called by muse, mutect2, varscan2
- RGS12 | c.613G>C p.D205H | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.854); catalogued as COSV100374622, COSV60903678; called by muse, mutect2, varscan2
- RHBDF2 | c.1636G>T p.G546W | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99166165; called by muse, mutect2, varscan2
- RHCG | c.1300G>A p.V434I | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.013); catalogued as rs1352826969, COSV99174043; called by muse, mutect2, varscan2
- RHD | c.16C>A p.P6T | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.53); catalogued as COSV100154835; called by muse, mutect2, varscan2
- RIMS1 | c.3001G>T p.V1001F | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT tolerated (0.7); PolyPhen benign (0.209); catalogued as COSV99323277; called by muse, mutect2, varscan2
- RIMS2 | c.3749G>T p.S1250I | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as rs748178817, COSV99155466; called by muse, mutect2, varscan2
- ROBO3 | c.1601G>A p.G534D | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.673); catalogued as COSV101184870; called by muse, mutect2, varscan2
- RPS9 | c.13C>G p.R5G | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.096); catalogued as COSV100256319; called by muse, mutect2, varscan2
- RYR2 | c.10592A>G p.Y3531C | Missense Mutation (SNP) | VAF 42/204 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs794728769, COSV100767324; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN4A | c.5392G>T p.A1798S | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0.003); catalogued as COSV101438291; called by muse, mutect2, varscan2
- SEMG2 | c.694A>G p.S232G | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.039); catalogued as COSV101033924; called by muse, mutect2, varscan2
- SERPINB8 | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.158); catalogued as COSV99728888; called by muse, mutect2, varscan2
- SEZ6L | c.1858A>T p.T620S | Missense Mutation (SNP) | VAF 80/166 reads (48%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.906); catalogued as COSV99961152; called by muse, mutect2, varscan2
- SHROOM3 | c.5165G>T p.R1722I | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.045); catalogued as COSV99933344; called by muse, mutect2, varscan2
- SI | c.1484A>C p.Q495P | Missense Mutation (SNP) | VAF 41/153 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.141); catalogued as COSV100013588; called by muse, mutect2
- SI | c.1483C>T p.Q495* | Nonsense Mutation (SNP) | VAF 40/151 reads (26%) | catalogued as COSV100013595, COSV52266423; called by muse, mutect2
- SLC18A2 | c.1342G>A p.G448R | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100041281; called by muse, mutect2, varscan2
- SLC26A7 | c.395C>A p.T132K | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.036); catalogued as COSV99402348; called by muse, mutect2, varscan2
- SLC29A3 | c.1213A>G p.K405E | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.85); PolyPhen benign (0.007); catalogued as COSV100928389; called by muse, mutect2, varscan2
- SLC30A10 | c.1040C>A p.A347D | Missense Mutation (SNP) | VAF 50/122 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100751394; called by muse, mutect2, varscan2
- SLC4A10 | c.168G>T p.L56F | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0.013); catalogued as COSV99762026; called by muse, mutect2
- SLC5A6 | c.424C>T p.R142* | Nonsense Mutation (SNP) | VAF 94/342 reads (27%) | catalogued as rs1558510783, COSV60161105; called by muse, mutect2, varscan2
- SLC6A5 | c.1555G>T p.V519F | Missense Mutation (SNP) | VAF 31/159 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100116312, COSV54224567; called by muse, mutect2, varscan2
- SLF1 | c.2362A>C p.K788Q | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99475509; called by muse, mutect2, varscan2
- SNCAIP | c.2487C>A p.S829R | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT tolerated (0.24); PolyPhen benign (0.034); catalogued as rs1353858733, COSV99746767; called by muse, mutect2, varscan2
- SNED1 | c.3092G>A p.R1031H | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs774944493, COSV100122074; called by mutect2, varscan2
- SNX18 | c.1316A>G p.D439G | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100410139; called by muse, mutect2
- SPATA16 | c.1349C>T p.P450L | Missense Mutation (SNP) | VAF 59/199 reads (30%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV100650803; called by muse, mutect2, varscan2
- SPATA31D1 | c.664C>A p.P222T | Missense Mutation (SNP) | VAF 55/147 reads (37%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.929); catalogued as rs1179072870, COSV100782412; called by muse, mutect2, varscan2
- SPATA31D1 | c.3163C>A p.P1055T | Missense Mutation (SNP) | VAF 74/162 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.079); catalogued as COSV100782414; called by muse, mutect2, varscan2
- SPHKAP | c.3587G>A p.R1196K | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.056); catalogued as rs763752247, COSV100763617; called by muse, mutect2, varscan2
- SPTB | c.5308G>A p.E1770K | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.559); catalogued as rs375893423; called by muse, mutect2, varscan2
- SRP72 | c.1245G>A p.M415I | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.119); catalogued as rs926204089, COSV100714235; called by muse, mutect2, varscan2
- STOX2 | c.2695C>T p.R899* | Nonsense Mutation (SNP) | VAF 5/18 reads (28%) | catalogued as rs369433755, COSV57854065; called by muse, mutect2, varscan2
- STYXL2 | c.1799T>C p.V600A | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.079); catalogued as COSV54805800, COSV54807118, COSV99608453; called by muse, mutect2, varscan2
- SYCP1 | c.2509G>C p.D837H | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.365); catalogued as COSV101050711, COSV65696860; called by muse, mutect2
- SYT1 | c.292G>T p.G98W | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV99693319; called by muse, mutect2, varscan2
- SYT1 | c.293G>T p.G98V | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.038); catalogued as COSV99693323; called by muse, mutect2, varscan2
- SYT16 | c.1094A>T p.Q365L | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV101413431; called by muse, mutect2, varscan2
- TACO1 | c.739G>T p.D247Y | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV99366402; called by muse, mutect2, varscan2
- TAF1L | c.3043C>G p.R1015G | Missense Mutation (SNP) | VAF 49/415 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54261243, COSV99644001; called by muse, mutect2, varscan2
- TAL1 | c.56G>T p.R19L | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV53748563, COSV99595847; called by mutect2, varscan2
- TBX18 | c.1329C>A p.N443K | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.07); catalogued as COSV100858377; called by muse, mutect2, varscan2
- TCHH | c.1006G>C p.E336Q | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.059); catalogued as COSV100914869, COSV100914889; called by muse, varscan2
- TECTA | c.3845G>A p.G1282E | Missense Mutation (SNP) | VAF 65/142 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as COSV99878317; called by muse, mutect2, varscan2
- TEKT5 | c.263G>T p.R88L | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs768273976, COSV51586722, COSV99295769; called by muse, mutect2, varscan2
- TENM4 | c.5804T>A p.L1935Q | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99570041; called by muse, mutect2
- TFB1M | c.872G>A p.R291Q | Missense Mutation (SNP) | VAF 23/185 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.382); catalogued as rs746305133, COSV99264966; called by muse, mutect2, varscan2
- TKTL2 | c.344G>A p.R115Q | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.842); catalogued as rs1560904567, COSV54918270; called by muse, mutect2, varscan2
- TMC7 | c.359G>T p.W120L | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as COSV100432222; called by muse, mutect2, varscan2
- TMEM132D | c.2411C>G p.P804R | Missense Mutation (SNP) | VAF 51/174 reads (29%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.965); catalogued as COSV101242516, COSV67160506; called by muse, mutect2, varscan2
- TMEM161B | c.290-1G>C p.X97_splice | Splice Site (SNP) | VAF 20/45 reads (44%) | catalogued as COSV53510318, COSV99494538; called by muse, mutect2, varscan2
- TMEM215 | c.577G>C p.E193Q | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV104418137, COSV61363505; called by muse, mutect2, varscan2
- TNFAIP6 | c.547G>C p.E183Q | Missense Mutation (SNP) | VAF 27/231 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99693635; called by muse, mutect2, varscan2
- TNR | c.1936G>C p.G646R | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs137958146, COSV99690265; called by muse, mutect2, varscan2
- TP53 | c.1001G>T p.G334V | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52689817, COSV52759537, COSV52925149; called by muse, mutect2, varscan2
- TPSG1 | c.538C>T p.R180W | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as rs199779684; called by muse, mutect2, varscan2
- TRAPPC9 | c.3367G>T p.D1123Y | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.466); catalogued as COSV101226440; called by muse, mutect2, varscan2
- TRIML1 | c.577G>T p.E193* | Nonsense Mutation (SNP) | VAF 25/70 reads (36%) | catalogued as COSV100205634; called by muse, mutect2, varscan2
- TTC5 | c.262G>T p.A88S | Missense Mutation (SNP) | VAF 63/124 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV99351495; called by muse, mutect2, varscan2
- TTN | c.26285T>C p.F8762S (on ENST00000591111; = p.F7835S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/72 reads (7%) | PolyPhen benign (0.013); catalogued as COSV100591264, COSV60384717; called by muse, mutect2
- TTN | c.2070T>A p.H690Q (on ENST00000591111; = p.H644Q on NM_003319.4) | Missense Mutation (SNP) | VAF 21/144 reads (15%) | PolyPhen benign (0.001); catalogued as COSV100591268; called by muse, mutect2, varscan2
- TUBA1A | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.25); catalogued as COSV99853603; called by muse, mutect2, varscan2
- UBE2E2 | c.218C>G p.P73R | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV100232202; called by muse, mutect2, varscan2
- UBR5 | c.6439C>T p.Q2147* | Nonsense Mutation (SNP) | VAF 55/147 reads (37%) | catalogued as COSV55303188, COSV99638993; called by muse, mutect2, varscan2
- UGT2B10 | c.523C>A p.P175T | Missense Mutation (SNP) | VAF 69/207 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.056); catalogued as COSV55324469, COSV99607779; called by muse, mutect2, varscan2
- UGT2B7 | c.1444G>T p.D482Y | Missense Mutation (SNP) | VAF 41/198 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1379588626, COSV100535079, COSV59442802; called by muse, mutect2, varscan2
- UNC13C | c.3200T>C p.I1067T | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.081); catalogued as COSV99510505; called by muse, mutect2, varscan2
- USP34 | c.7283T>C p.M2428T | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV101276552; called by muse, mutect2, varscan2
- VNN2 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs962925338, COSV100426682, COSV58472413; called by muse, mutect2
- VPREB3 | c.168G>T p.W56C | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99963444; called by muse, mutect2, varscan2
- VPS41 | c.2425G>T p.V809L | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated (0.62); PolyPhen benign (0.04); catalogued as COSV100053448; called by muse, mutect2, varscan2
- WAC | c.608G>A p.G203E | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.173); catalogued as COSV100610833; called by muse, mutect2
- WDR3 | c.309C>G p.F103L | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.957); catalogued as COSV100831935; called by muse, mutect2, varscan2
- WNT3A | c.590G>C p.S197T | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.139); catalogued as COSV99468646; called by muse, mutect2, varscan2
- WNT6 | c.636+1G>T p.X212_splice | Splice Site (SNP) | VAF 10/20 reads (50%) | catalogued as COSV99293081; called by muse, mutect2, varscan2
- WWC3 | c.2937del p.Q980Rfs*4 | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | catalogued as COSV101082009; called by mutect2, pindel, varscan2
- XRN1 | c.4623G>T p.W1541C | Missense Mutation (SNP) | VAF 76/197 reads (39%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.417); catalogued as COSV53817935; called by muse, mutect2, varscan2
- YTHDC2 | c.841A>T p.R281W | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99362822; called by muse, mutect2, varscan2
- ZBP1 | c.764A>T p.H255L | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.125); catalogued as COSV100472939; called by muse, mutect2
- ZC3H14 | c.929A>G p.H310R | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1385225123, COSV99192940; called by muse, mutect2, varscan2
- ZEB2 | c.862G>T p.G288C | Missense Mutation (SNP) | VAF 53/238 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100354780; called by muse, mutect2, varscan2
- ZFAND1 | c.186C>G p.Y62* | Nonsense Mutation (SNP) | VAF 12/45 reads (27%) | catalogued as rs150915150; called by muse, mutect2, varscan2
- ZFAND4 | c.329-1G>T p.X110_splice | Splice Site (SNP) | VAF 5/44 reads (11%) | catalogued as rs867358284, COSV100084428; called by muse, mutect2
- ZFAND6 | c.202G>C p.D68H | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.417); catalogued as rs776947151, COSV55712421, COSV99928350; called by muse, mutect2, varscan2
- ZNF208 | c.1108A>G p.K370E | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.991); catalogued as COSV101236689; called by muse, mutect2, varscan2
- ZNF213 | c.1022G>C p.G341A | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV101205918; called by muse, mutect2
- ZNF462 | c.6733G>C p.A2245P | Missense Mutation (SNP) | VAF 84/209 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV99470587; called by muse, mutect2, varscan2
- ZNF511-PRAP1 | c.672C>A p.D224E | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.9); catalogued as COSV99529328; called by muse, mutect2, varscan2
- ZNF613 | c.712G>T p.G238W (on ENST00000293471 / NM_001031721.4; = p.G202W on NM_024840.4) | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99522821; called by muse, mutect2
- ZNF622 | c.863T>C p.I288T | Missense Mutation (SNP) | VAF 29/218 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as rs745944907, COSV100432964; called by muse, mutect2, varscan2
- ZNF829 | c.1225G>C p.D409H | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV101199559; called by muse, mutect2, varscan2
- ZNF99 | c.1256A>G p.H419R | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs766808532, COSV101233649; called by muse, mutect2, varscan2
- ZP4 | c.1532G>C p.G511A | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.232); catalogued as COSV100850505; called by muse, mutect2, varscan2
- ARHGEF10L | c.2438del p.G813Vfs*32 | Frame Shift Del (DEL) | VAF 89/265 reads (34%) | called by mutect2, pindel, varscan2
- ASAH2 | c.1692C>A p.N564K | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- F13A1 | c.1909-6_1911dup p.V637_R638insS* | Nonsense Mutation (INS) | VAF 10/31 reads (32%) | called by mutect2, varscan2
- GTF2IRD2B | c.1391G>T p.R464L | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by mutect2, varscan2
- GUCY2C | c.1047dup p.K350Qfs*12 | Frame Shift Ins (INS) | VAF 25/169 reads (15%) | called by mutect2, pindel, varscan2
- IL18RAP | c.771del p.E258Rfs*6 | Frame Shift Del (DEL) | VAF 24/74 reads (32%) | called by pindel, varscan2
- KIFC2 | c.1585_1587del p.E529del | In Frame Del (DEL) | VAF 15/84 reads (18%) | called by mutect2, pindel, varscan2
- LY75 | c.4324del p.E1442Kfs*4 | Frame Shift Del (DEL) | VAF 85/246 reads (35%) | called by mutect2, pindel, varscan2
- MMP16 | c.1347del p.T451Pfs*16 | Frame Shift Del (DEL) | VAF 13/63 reads (21%) | called by mutect2, pindel, varscan2
- MRC1 | c.1736C>A p.T579N | Missense Mutation (SNP) | VAF 52/175 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- MUC2 | c.43T>G p.L15V | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT tolerated, low confidence (0.35); called by muse, mutect2
- RIMS2 | c.225G>T p.M75I | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (1); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- ZNF607 | c.1617del p.K540Sfs*184 | Frame Shift Del (DEL) | VAF 8/70 reads (11%) | called by mutect2, varscan2
- ADAMTS12 | c.294G>A p.E98= | Silent (SNP) | VAF 41/327 reads (13%) | catalogued as rs1018848012, COSV61256476; called by muse, mutect2, varscan2
- ADAMTS20 | c.513T>C p.D171= | Silent (SNP) | VAF 43/137 reads (31%) | catalogued as COSV101238751; called by muse, mutect2, varscan2
- ADAMTS5 | c.1836C>T p.I612= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV99536925; called by muse, mutect2, varscan2
- ADAMTSL1 | c.3132G>T p.A1044= | Silent (SNP) | VAF 5/9 reads (56%) | catalogued as rs751072322, COSV101001120; called by muse, mutect2, varscan2
- AGBL1 | c.2757C>A p.T919= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as rs373021524; called by muse, mutect2, varscan2
- AHRR | c.1365G>T p.P455= | Silent (SNP) | VAF 96/142 reads (68%) | catalogued as COSV100326475; called by muse, mutect2, varscan2
- ALMS1 | c.12285G>T p.P4095= | Silent (SNP) | VAF 29/92 reads (32%) | catalogued as rs776912137, COSV100040904; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- ATP9A | c.1002C>T p.R334= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as COSV100124212; called by muse, mutect2, varscan2
- ATP9B | c.2700G>C p.S900= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV100302656; called by muse, varscan2
- BAG6 | c.600A>G p.P200= | Silent (SNP) | VAF 37/220 reads (17%) | catalogued as COSV99276288; called by muse, mutect2, varscan2
- BIRC6 | c.3135C>T p.C1045= | Silent (SNP) | VAF 16/73 reads (22%) | catalogued as COSV101427750; called by muse, mutect2, varscan2
- BIRC6 | c.11598A>G p.L3866= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as COSV101427752; called by muse, mutect2, varscan2
- C22orf42 | c.151T>C p.L51= | Silent (SNP) | VAF 32/235 reads (14%) | catalogued as COSV101173265; called by muse, mutect2, varscan2
- CHRM3 | c.633T>A p.V211= | Silent (SNP) | VAF 33/208 reads (16%) | catalogued as COSV99697279; called by muse, mutect2, varscan2
- CLRN2 | c.561G>A p.E187= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as COSV101492680; called by muse, mutect2, varscan2
- CNGB3 | c.1242A>G p.P414= | Silent (SNP) | VAF 23/50 reads (46%) | catalogued as rs1225608783, COSV100181053; called by muse, mutect2, varscan2
- CRBN | c.495C>T p.F165= | Silent (SNP) | VAF 20/106 reads (19%) | catalogued as COSV99214013; called by muse, mutect2, varscan2
- DBX1 | c.733C>T p.L245= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as COSV99910076; called by muse, mutect2, varscan2
- DGKG | c.438C>A p.P146= | Silent (SNP) | VAF 57/418 reads (14%) | catalogued as rs746506410, COSV99402245; called by muse, mutect2, varscan2
- DNAJC14 | c.1203G>A p.L401= | Silent (SNP) | VAF 21/155 reads (14%) | catalogued as COSV100423495, COSV57913603; called by muse, mutect2, varscan2
- DNMT1 | c.687G>T p.T229= | Silent (SNP) | VAF 10/90 reads (11%) | catalogued as COSV100531621, COSV61584316; called by muse, mutect2, varscan2
- DUOX1 | c.3261G>C p.R1087= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as COSV100367553; called by muse, mutect2, varscan2
- EBF3 | c.1308C>T p.G436= (on ENST00000355311 / NM_001375392.1; = p.G427= on NM_001005463.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/123 reads (23%) | catalogued as rs768053904, COSV100798963; called by muse, mutect2, varscan2
- ETFBKMT | c.522G>A p.L174= | Silent (SNP) | VAF 19/78 reads (24%) | catalogued as COSV99861391; called by muse, mutect2, varscan2
- FAM160A2 | c.639T>C p.F213= | Silent (SNP) | VAF 50/276 reads (18%) | catalogued as rs1488612642, COSV99791631; called by muse, mutect2, varscan2
- FAM189A2 | c.520C>T p.L174= | Silent (SNP) | VAF 48/179 reads (27%) | catalogued as COSV99974652; called by muse, mutect2, varscan2
- FAM210B | c.207G>T p.G69= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV100452739; called by muse, mutect2, varscan2
- FAM47A | c.1440G>T p.P480= | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as rs779152090, COSV100649674, COSV60500362; called by muse, mutect2, varscan2
- FCGBP | c.4305G>C p.P1435= | Silent (SNP) | VAF 40/77 reads (52%) | catalogued as COSV99660503; called by muse, mutect2, varscan2
- FCGBP | c.2919G>A p.T973= | Silent (SNP) | VAF 42/91 reads (46%) | catalogued as rs770922108; called by muse, mutect2, varscan2
- GATA4 | c.1227C>A p.G409= | Silent (SNP) | VAF 34/72 reads (47%) | catalogued as COSV100632761; called by muse, mutect2, varscan2
- GLG1 | c.1587G>T p.L529= | Silent (SNP) | VAF 30/124 reads (24%) | catalogued as COSV52664216, COSV99215184; called by muse, mutect2, varscan2
- GPR15 | c.1082A>G p.*361= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as COSV99423606; called by muse, mutect2, varscan2
- GPR50 | c.1521G>A p.K507= | Silent (SNP) | VAF 51/95 reads (54%) | catalogued as COSV99505539; called by muse, mutect2, varscan2
- GRIA2 | c.432A>G p.Q144= | Silent (SNP) | VAF 57/179 reads (32%) | catalogued as rs772821769, COSV99642663; called by muse, mutect2, varscan2
- H2BC3 | c.312T>A p.P104= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV100778237; called by muse, mutect2, varscan2
- HFM1 | c.3006G>T p.T1002= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV54023987, COSV99645186; called by muse, mutect2, varscan2
- HRNR | c.6246C>G p.G2082= | Silent (SNP) | VAF 65/181 reads (36%) | catalogued as COSV100912781, COSV100913299; called by muse, mutect2, varscan2
- IGF1R | c.927G>A p.S309= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as rs772738892, COSV99148206; called by muse, mutect2, varscan2
- IRS1 | c.1245G>C p.S415= | Silent (SNP) | VAF 29/146 reads (20%) | catalogued as rs759117890, COSV100523844, COSV100524447; called by muse, mutect2, varscan2
- ITGBL1 | c.1236G>A p.K412= | Silent (SNP) | VAF 7/144 reads (5%) | catalogued as rs1566800125, COSV101094973, COSV66008597; called by muse, mutect2
- KCNJ11 | c.723G>A p.E241= | Silent (SNP) | VAF 11/69 reads (16%) | catalogued as COSV100378949; called by muse, mutect2, varscan2
- LDLRAD3 | c.222C>T p.T74= | Silent (SNP) | VAF 24/117 reads (21%) | catalogued as COSV100214230; called by muse, mutect2, varscan2
- LRRC7 | c.381T>A p.A127= (on ENST00000651989 / NM_001370785.2; = p.A94= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 23/113 reads (20%) | catalogued as COSV99224041; called by muse, mutect2, varscan2
- MAGEB6B | c.747C>A p.G249= | Silent (SNP) | VAF 12/34 reads (35%) | called by muse, mutect2, varscan2
- MMADHC | c.579A>G p.V193= | Silent (SNP) | VAF 7/97 reads (7%) | catalogued as rs1461075501, COSV100307065; called by muse, mutect2
- MRC1 | c.1737C>T p.T579= | Silent (SNP) | VAF 54/176 reads (31%) | called by muse, mutect2, varscan2
- MROH2B | c.4560C>A p.I1520= | Silent (SNP) | VAF 123/175 reads (70%) | catalogued as COSV101270438, COSV68187594; called by muse, mutect2, varscan2
- MTUS1 | c.78A>G p.T26= | Silent (SNP) | VAF 69/119 reads (58%) | catalogued as COSV100028700; called by muse, mutect2, varscan2
- MYO1A | c.1683G>T p.P561= | Silent (SNP) | VAF 25/90 reads (28%) | catalogued as COSV55651673; called by muse, mutect2, varscan2
- NAP1L1 | c.180A>T p.V60= | Silent (SNP) | VAF 44/136 reads (32%) | catalogued as COSV99673626; called by muse, mutect2, varscan2
- NLRP11 | c.612C>A p.A204= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as COSV100789613; called by muse, mutect2, varscan2
- NR5A2 | c.600C>A p.I200= (on ENST00000367362 / NM_205860.3; = p.I154= on NM_003822.5) | Silent (SNP) | VAF 56/148 reads (38%) | catalogued as rs1467389931, COSV99370557; called by muse, varscan2
- OLFM3 | c.1014C>A p.P338= (on ENST00000338858 / NM_001288821.1; = p.P318= on NM_058170.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as COSV100128786; called by muse, mutect2, varscan2
- OR1S1 | c.615A>G p.T205= | Silent (SNP) | VAF 29/112 reads (26%) | catalogued as COSV100515209; called by muse, mutect2, varscan2
- OR6K2 | c.498A>C p.P166= | Silent (SNP) | VAF 25/67 reads (37%) | catalogued as COSV100656660; called by muse, mutect2, varscan2
- OR9I1 | c.303C>T p.F101= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as rs758585477, COSV56925524, COSV56927049; called by muse, mutect2, varscan2
- PATE1 | c.328T>C p.L110= | Silent (SNP) | VAF 14/127 reads (11%) | catalogued as COSV99986068; called by muse, mutect2, varscan2
- PCDH10 | c.1638G>T p.R546= | Silent (SNP) | VAF 15/90 reads (17%) | catalogued as COSV52105442, COSV99992766; called by muse, mutect2, varscan2
- PCDH11X | c.345G>A p.L115= | Silent (SNP) | VAF 41/77 reads (53%) | catalogued as COSV100007415; called by muse, mutect2, varscan2
- PCDHB11 | c.492C>T p.I164= | Silent (SNP) | VAF 44/94 reads (47%) | catalogued as COSV99503548; called by muse, mutect2, varscan2
- POU1F1 | c.387C>A p.I129= | Silent (SNP) | VAF 42/100 reads (42%) | catalogued as COSV100622577; called by muse, mutect2, varscan2
- PPP2R5C | c.1230A>G p.Q410= | Silent (SNP) | VAF 43/78 reads (55%) | catalogued as COSV100158966; called by muse, mutect2, varscan2
- PWWP3A | c.1227G>A p.S409= (on ENST00000627377; = p.S408= on NM_032853.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as rs368181378; called by muse, mutect2, varscan2
- RPP38 | c.360T>A p.V120= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV100975455; called by muse, mutect2, varscan2
- RPTOR | c.141G>A p.Q47= | Silent (SNP) | VAF 50/160 reads (31%) | catalogued as COSV100154746; called by muse, mutect2, varscan2
- RREB1 | c.3135G>T p.L1045= | Silent (SNP) | VAF 33/105 reads (31%) | catalogued as COSV100619064; called by muse, mutect2, varscan2
- RSPH3 | c.1587A>G p.S529= (on ENST00000252655; = p.S387= on NM_031924.8) | Silent (SNP) | VAF 96/244 reads (39%) | catalogued as COSV99396085; called by muse, mutect2, varscan2
- SEC24C | c.378C>G p.P126= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as COSV100226465; called by muse, mutect2
- SLC30A10 | c.1041C>A p.A347= | Silent (SNP) | VAF 51/127 reads (40%) | catalogued as COSV100751393; called by muse, mutect2, varscan2
- TAF4B | c.591A>T p.S197= | Silent (SNP) | VAF 7/121 reads (6%) | catalogued as COSV99299481; called by muse, mutect2
- TECTA | c.2445G>T p.T815= | Silent (SNP) | VAF 37/256 reads (14%) | catalogued as COSV99878316; called by muse, mutect2, varscan2
- TFDP3 | c.807C>T p.C269= | Silent (SNP) | VAF 81/126 reads (64%) | catalogued as rs751374865, COSV100033166; called by muse, mutect2, varscan2
- TNPO3 | c.318G>A p.T106= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs140754153; ClinVar: uncertain significance / likely benign; called by mutect2, varscan2
- TRIM2 | c.1263G>A p.V421= (on ENST00000437508; = p.V448= on NM_015271.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 16/94 reads (17%) | catalogued as COSV100107468; called by muse, mutect2, varscan2
- TTN | c.22401G>C p.T7467= (on ENST00000591111; = p.T6540= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 40/203 reads (20%) | catalogued as COSV100591267; called by muse, mutect2, varscan2
- XRCC5 | c.1776G>T p.V592= | Silent (SNP) | VAF 22/53 reads (42%) | catalogued as COSV101079214; called by muse, mutect2, varscan2
- ZNF677 | c.1551T>C p.C517= | Silent (SNP) | VAF 20/83 reads (24%) | catalogued as COSV100447748; called by muse, mutect2, varscan2
- ZRANB3 | c.2802G>A p.R934= | Silent (SNP) | VAF 60/288 reads (21%) | catalogued as rs757413791, COSV99922411; called by muse, mutect2, varscan2
- DCHS2 | n.4888C>T | RNA (SNP) | VAF 14/61 reads (23%) | catalogued as COSV100600928, COSV61770728, COSV61775894; called by muse, mutect2, varscan2
- FOLH1B | n.1628G>A | RNA (SNP) | VAF 37/98 reads (38%) | called by muse, mutect2, varscan2
- GRM1 | c.-1C>A | 5'UTR (SNP) | VAF 22/205 reads (11%) | catalogued as COSV99263550, COSV99264718; called by muse, mutect2, varscan2
- ISCA1P1 | n.26C>A | RNA (SNP) | VAF 11/27 reads (41%) | called by muse, mutect2, varscan2
- MASP1 | c.1303+5596A>T | Intron (SNP) | VAF 4/36 reads (11%) | catalogued as COSV99961749; called by mutect2, varscan2
- PAXBP1 | c.2334+1684G>T | Intron (SNP) | VAF 8/12 reads (67%) | catalogued as COSV99268972; called by muse, mutect2, varscan2
- PDE4B | c.635-77C>A | Intron (SNP) | VAF 17/86 reads (20%) | catalogued as COSV100301913; called by muse, mutect2, varscan2
- SYNGR1 | c.100-10071C>A | Intron (SNP) | VAF 38/150 reads (25%) | catalogued as COSV99335453; called by muse, mutect2, varscan2
